Somatic mutation profile of tumor specimen HCM-BROD-0104-C71-01A (aliquot HCM-BROD-0104-C71-01A-11D-A78T-36) from HCMI case HCM-BROD-0104-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.0 years (23,020 days).
Specimen HCM-BROD-0104-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 694e29c5-d252-441e-b52a-6e2dd4c52404.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0104-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0104-C71-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e9aabea-00ce-4e03-82fd-ba55b66ec470

The open-access MAF lists 94 somatic variants for this specimen: 63 protein-altering or splice-affecting, 22 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 22, Intron 6, Nonsense Mutation 3, 3'Flank 2, Frame Shift Del 2, In Frame Del 1, Splice Region 1, RNA 1, Splice Site 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PDGFRA | c.1975A>T p.N659Y | Missense Mutation (SNP) | VAF 109/288 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57265460, COSV57275286; called by muse, mutect2, varscan2
- PIK3R1 | c.1351_1356del p.E451_Y452del (on ENST00000521381 / NM_181523.3; = p.E181_Y182del on NM_181504.4) | In Frame Del (DEL) | VAF 20/72 reads (28%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ADPRS | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 133/315 reads (42%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as rs1398056859; called by muse, mutect2, varscan2
- AFF1 | c.1874G>A p.R625K | Missense Mutation (SNP) | VAF 80/205 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV57117673; called by muse, varscan2
- ANKRD65 | c.955G>A p.G319S | Missense Mutation (SNP) | VAF 141/322 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368780971; called by muse, mutect2, varscan2
- BCLAF1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.306); catalogued as COSV62140394; called by muse, mutect2, varscan2
- BCLAF1 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62140517; called by muse, mutect2, varscan2
- BPIFA1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 176/491 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as rs6120181; called by muse, mutect2, varscan2
- CCSER1 | c.2296C>A p.R766S | Missense Mutation (SNP) | VAF 17/233 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.066); catalogued as rs569829898, COSV61446572; called by muse, mutect2
- CD1E | c.431G>C p.G144A | Missense Mutation (SNP) | VAF 110/283 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63770040; called by muse, mutect2, varscan2
- CDNF | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 71/102 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101012365; called by muse, mutect2, varscan2
- CFAP251 | c.3313G>A p.E1105K | Missense Mutation (SNP) | VAF 139/402 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs1037654630; called by muse, mutect2, varscan2
- CGNL1 | c.3136G>A p.E1046K | Missense Mutation (SNP) | VAF 133/311 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs372428898; called by muse, mutect2, varscan2
- DAAM2 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 238/533 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1390440173, COSV51417930, COSV51419283; called by muse, varscan2
- EMD | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 90/216 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1169279026; called by muse, mutect2, varscan2
- ERICH6 | c.1209C>G p.N403K | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762527505, COSV55803675; called by muse, mutect2, varscan2
- FREM1 | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 152/393 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs369488195, COSV66527572; called by muse, mutect2, varscan2
- FRMD4B | c.1997C>T p.T666M | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201890981; called by muse, mutect2, varscan2
- G6PC | c.1012G>A p.V338I | Missense Mutation (SNP) | VAF 93/248 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.144); catalogued as rs367727229, CM980787; called by muse, mutect2, varscan2
- HIF3A | c.1243C>T p.R415C (on ENST00000377670 / NM_152795.4; = p.R346C on NM_022462.4) | Missense Mutation (SNP) | VAF 117/330 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1039626444, COSV99355793; called by muse, mutect2, varscan2
- HSD3B2 | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 149/393 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs748851282, COSV101027530; called by muse, mutect2, varscan2
- ISYNA1 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 137/577 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV53214078; called by muse, mutect2, varscan2
- KCNK1 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.247); catalogued as rs1400981676, COSV64035238; called by muse, mutect2
- MAP3K9 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 90/247 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751015012, COSV67122589; called by muse, mutect2, varscan2
- MS4A14 | c.662C>A p.P221Q | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.703); catalogued as COSV100280409; called by muse, mutect2, varscan2
- OIT3 | c.1282G>A p.G428S | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT tolerated (0.28); PolyPhen probably damaging (1); catalogued as rs140962729; called by muse, mutect2, varscan2
- OR2T2 | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 36/276 reads (13%) | catalogued as rs759702597, COSV100737533; called by mutect2, varscan2
- PCLO | c.9824G>A p.R3275Q | Missense Mutation (SNP) | VAF 104/385 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs1562876553, COSV104415074, COSV61633321; called by muse, mutect2, varscan2
- PPA1 | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 76/192 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs146821187; called by muse, mutect2, varscan2
- PTPRR | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 198/427 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.207); catalogued as rs567626445, COSV51726651, COSV99315904; called by muse, mutect2, varscan2
- SLC5A4 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 156/370 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as rs755635977, COSV56670823; called by muse, varscan2
- SLC5A8 | c.1691A>G p.N564S | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.11); catalogued as rs1177418877; called by muse, mutect2, varscan2
- ZNF251 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as rs773135594, COSV52959513; called by muse, mutect2, varscan2
- ZNF33B | c.2063C>T p.T688M | Missense Mutation (SNP) | VAF 130/160 reads (81%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs751588162; called by muse, mutect2, varscan2
- ZNF347 | c.729C>G p.I243M | Missense Mutation (SNP) | VAF 72/200 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.033); catalogued as COSV100498438; called by muse, mutect2, varscan2
- ZNF99 | c.1804T>G p.F602V | Missense Mutation (SNP) | VAF 24/840 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV68055953; called by muse, mutect2
- ANK3 | c.9260A>C p.K3087T | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ANKRD30B | c.3233A>G p.N1078S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.061); called by muse, varscan2
- ANKRD54 | c.377-1G>A p.X126_splice | Splice Site (SNP) | VAF 97/228 reads (43%) | called by muse, mutect2, varscan2
- ARHGEF35 | c.1372T>C p.C458R | Missense Mutation (SNP) | VAF 88/493 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- BCLAF1 | c.798G>C p.Q266H | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- CCDC141 | c.3626T>C p.V1209A | Missense Mutation (SNP) | VAF 127/326 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CCNF | c.742_743del p.R248Gfs*33 | Frame Shift Del (DEL) | VAF 138/410 reads (34%) | called by mutect2, pindel, varscan2
- CEL | c.803G>A p.G268D (on ENST00000673714; = p.G265D on NM_001807.6) | Missense Mutation (SNP) | VAF 297/666 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- DCAF8L2 | c.1168T>A p.F390I | Missense Mutation (SNP) | VAF 116/285 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- GNL3L | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/248 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); called by muse, mutect2
- GRM1 | c.528G>T p.Q176H | Missense Mutation (SNP) | VAF 249/560 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HMGB3 | c.455A>C p.K152T | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- IRAK3 | c.1018T>C p.Y340H | Missense Mutation (SNP) | VAF 89/211 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ISL1 | c.659T>A p.L220H | Missense Mutation (SNP) | VAF 223/514 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KEL | c.1315-5C>A | Splice Region (SNP) | VAF 189/660 reads (29%) | called by muse, mutect2, varscan2
- LRP1 | c.5587C>T p.P1863S | Missense Mutation (SNP) | VAF 76/320 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- LYL1 | c.597C>G p.I199M | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO1B | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 57/160 reads (36%) | called by muse, mutect2, varscan2
- NFYC | c.1199G>A p.R400K | Missense Mutation (SNP) | VAF 180/394 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- NTAQ1 | c.118A>G p.K40E | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- OR8B8 | c.802A>C p.M268L | Missense Mutation (SNP) | VAF 17/325 reads (5%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2
- P2RY4 | c.853A>C p.N285H | Missense Mutation (SNP) | VAF 155/355 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RIMS2 | c.4330G>C p.V1444L (on ENST00000666250 / NM_001348490.2; = p.V1015L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- RPGRIP1L | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 94/214 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RYR3 | c.11047del p.S3683Lfs*12 (on ENST00000389232; = p.S3684Lfs*12 on NM_001036.6) | Frame Shift Del (DEL) | VAF 27/93 reads (29%) | called by mutect2, pindel, varscan2
- SYTL5 | c.959C>G p.S320* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2, varscan2
- ZNF347 | c.524C>G p.A175G | Missense Mutation (SNP) | VAF 80/231 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- ACY3 | c.852C>T p.N284= | Silent (SNP) | VAF 272/686 reads (40%) | catalogued as rs146627401; called by muse, mutect2, varscan2
- ADAD2 | c.159C>T p.R53= | Silent (SNP) | VAF 53/107 reads (50%) | catalogued as rs1360227408, COSV51895041; called by muse, mutect2
- CACNA1E | c.312C>T p.I104= | Silent (SNP) | VAF 105/305 reads (34%) | catalogued as rs760287778; called by muse, mutect2, varscan2
- IDS | c.357C>T p.I119= | Silent (SNP) | VAF 124/357 reads (35%) | catalogued as rs782362742; ClinVar: likely benign; called by muse, mutect2, varscan2
- KIDINS220 | c.4690A>C p.R1564= | Silent (SNP) | VAF 85/187 reads (45%) | called by muse, mutect2, varscan2
- MMP13 | c.840G>A p.T280= | Silent (SNP) | VAF 148/374 reads (40%) | catalogued as rs782436272; called by muse, mutect2, varscan2
- NUP107 | c.156C>T p.I52= | Silent (SNP) | VAF 38/103 reads (37%) | catalogued as rs1303882637; called by muse, mutect2, varscan2
- OR8B2 | c.585C>T p.N195= | Silent (SNP) | VAF 70/201 reads (35%) | catalogued as rs761030464, COSV66664104; called by muse, mutect2, varscan2
- PLEKHG6 | c.205C>T p.L69= | Silent (SNP) | VAF 122/257 reads (47%) | called by muse, mutect2, varscan2
- PLEKHH3 | c.1080C>T p.T360= | Silent (SNP) | VAF 92/214 reads (43%) | catalogued as COSV52219673, COSV99257894; called by muse, mutect2, varscan2
- PLOD1 | c.729C>T p.N243= | Silent (SNP) | VAF 86/215 reads (40%) | catalogued as rs567164584, COSV52140360; called by muse, mutect2, varscan2
- PPL | c.1839G>A p.V613= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as rs1286670495; called by muse, mutect2, varscan2
- PRR16 | c.729G>A p.K243= (on ENST00000407149 / NM_001300783.2; = p.K220= on NM_016644.2) | Silent (SNP) | VAF 37/95 reads (39%) | called by muse, mutect2, varscan2
- REV1 | c.2733G>A p.G911= | Silent (SNP) | VAF 30/88 reads (34%) | called by muse, mutect2, varscan2
- SAMSN1 | c.516G>A p.T172= | Silent (SNP) | VAF 97/287 reads (34%) | catalogued as rs745867626, COSV53467189; called by muse, mutect2, varscan2
- SIX5 | c.396G>A p.L132= | Silent (SNP) | VAF 16/302 reads (5%) | called by muse, mutect2
- SKI | c.375G>A p.Q125= | Silent (SNP) | VAF 217/592 reads (37%) | called by muse, mutect2, varscan2
- SLC6A4 | c.819C>T p.G273= | Silent (SNP) | VAF 45/119 reads (38%) | catalogued as rs200745147; called by muse, mutect2, varscan2
- SPAM1 | c.354T>C p.I118= | Silent (SNP) | VAF 46/208 reads (22%) | called by muse, mutect2, varscan2
- WASHC4 | c.3042T>C p.Y1014= | Silent (SNP) | VAF 102/245 reads (42%) | called by muse, mutect2, varscan2
- ZNF347 | c.1062C>T p.F354= | Silent (SNP) | VAF 30/175 reads (17%) | catalogued as rs769820418; called by muse, mutect2, varscan2
- ZSCAN10 | c.1785G>A p.A595= (on ENST00000252463; = p.A650= on NM_032805.3) | Silent (SNP) | VAF 115/293 reads (39%) | catalogued as rs1303958259, COSV52966844; called by muse, mutect2, varscan2
- AC133561.1 | n.1376T>C | RNA (SNP) | VAF 119/297 reads (40%) | called by muse, mutect2, varscan2
- AP2A2 | c.67+14753C>A | Intron (SNP) | VAF 90/220 reads (41%) | catalogued as rs751886019; called by muse, mutect2, varscan2
- C8orf34 | c.1106-14731C>T | Intron (SNP) | VAF 37/105 reads (35%) | catalogued as rs761266402, COSV57395926; called by muse, mutect2, varscan2
- MMP9 | c.1902-13C>T | Intron (SNP) | VAF 163/413 reads (39%) | catalogued as rs1384158377, COSV63434234; called by muse, mutect2, varscan2
- ODF2L | chr1:86348928 C>A | 3'Flank (SNP) | VAF 21/58 reads (36%) | called by muse, mutect2, varscan2
- PSG6 | chr19:42902435 C>A | 3'Flank (SNP) | VAF 76/294 reads (26%) | called by muse, varscan2
- RANGRF | c.438-50A>G | Intron (SNP) | VAF 67/173 reads (39%) | called by muse, mutect2, varscan2
- TTN | c.10360+4436C>T | Intron (SNP) | VAF 46/115 reads (40%) | catalogued as rs369566893; called by muse, mutect2, varscan2
- WDR74 | c.65-29C>T | Intron (SNP) | VAF 92/228 reads (40%) | called by muse, mutect2, varscan2
